Somatic mutation profile of tumor specimen TCGA-2Y-A9H2-01A (aliquot TCGA-2Y-A9H2-01A-12D-A382-10) from TCGA case TCGA-2Y-A9H2, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 64.8 years (23,653 days).
Specimen TCGA-2Y-A9H2-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 01717892-c208-4b78-93af-0b8e612e63e5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2Y-A9H2-10A (Blood Derived Normal), aliquot TCGA-2Y-A9H2-10A-01D-A385-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c1772d5f-3903-426c-a634-7fee293a20c1

The open-access MAF lists 55 somatic variants for this specimen: 42 protein-altering or splice-affecting, 13 silent.
By variant classification: Missense Mutation 30, Silent 13, Nonsense Mutation 3, Frame Shift Del 2, In Frame Del 2, Splice Site 2, Frame Shift Ins 2, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRV1 | c.15904A>G p.I5302V | Missense Mutation (SNP) | VAF 37/164 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV101315524; called by muse, mutect2, varscan2
- AFF4 | c.169G>A p.G57R | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54791477, COSV99534619; called by muse, mutect2, varscan2
- ANKRD26 | c.4064A>C p.E1355A | Missense Mutation (SNP) | VAF 28/229 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.112); catalogued as COSV101062952; called by muse, mutect2, varscan2
- BCDIN3D | c.1A>C p.M1? | Translation Start Site (SNP) | VAF 21/121 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV100445464, COSV61702816; called by muse, mutect2, varscan2
- C8orf33 | c.427C>T p.R143* | Nonsense Mutation (SNP) | VAF 39/181 reads (22%) | catalogued as rs376887084, COSV100510546; called by muse, mutect2, varscan2
- CEP44 | c.304G>A p.A102T | Missense Mutation (SNP) | VAF 35/231 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV56660384, COSV99639205; called by muse, mutect2, varscan2
- COL4A1 | c.2022G>C p.R674S | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.974); catalogued as rs755517991, COSV101010969; called by muse, mutect2, varscan2
- CPAMD8 | c.4608G>T p.M1536I (on ENST00000651564; = p.M1489I on NM_015692.5) | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT tolerated (0.27); PolyPhen benign (0.089); catalogued as COSV101488417; called by muse, mutect2, varscan2
- DPEP1 | c.445A>G p.S149G | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99878312; called by muse, mutect2, varscan2
- DYNC1H1 | c.5630A>G p.D1877G | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as COSV100794488; called by muse, mutect2, varscan2
- EED | c.769G>A p.D257N | Missense Mutation (SNP) | VAF 19/130 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99646128; called by muse, mutect2, varscan2
- GPC1 | c.1633C>T p.L545F | Missense Mutation (SNP) | VAF 84/179 reads (47%) | SIFT tolerated (0.32); PolyPhen benign (0.077); catalogued as COSV50864160; called by muse, mutect2, varscan2
- GRN | c.1102_1104del p.N368del | In Frame Del (DEL) | VAF 11/70 reads (16%) | catalogued as rs1486380359; called by mutect2, pindel, varscan2
- HCN4 | c.1178G>A p.R393H | Missense Mutation (SNP) | VAF 63/138 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs786205804, COSV56081300; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HSPA12A | c.1873C>T p.R625C | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT tolerated (0.27); PolyPhen benign (0.066); catalogued as rs575047261, COSV65022514, COSV65022894; called by muse, mutect2, varscan2
- ITPR1 | c.1051A>G p.M351V (on ENST00000354582; = p.M336V on NM_002222.7) | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV100229711; called by muse, mutect2, varscan2
- LGR6 | c.2347G>T p.G783W (on ENST00000367278 / NM_001017403.1; = p.G731W on NM_021636.3) | Missense Mutation (SNP) | VAF 5/59 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55155599, COSV99706118; called by muse, mutect2
- MORC2 | c.401T>G p.F134C (on ENST00000397641 / NM_001303256.3; = p.F72C on NM_014941.3) | Missense Mutation (SNP) | VAF 41/148 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99309492; called by muse, mutect2
- MXRA5 | c.8188G>A p.A2730T | Missense Mutation (SNP) | VAF 16/114 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs371025447, COSV54222132, COSV99475900; called by muse, mutect2, varscan2
- NBEA | c.5848A>T p.N1950Y | Missense Mutation (SNP) | VAF 38/164 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100077063; called by muse, mutect2, varscan2
- NLGN4X | c.1434C>A p.S478R | Missense Mutation (SNP) | VAF 86/292 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); catalogued as COSV52016572, COSV99320047; called by muse, mutect2, varscan2
- NOS3 | c.994G>A p.A332T | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs749115207, COSV52490136, COSV99871256; called by muse, mutect2, varscan2
- OR3A1 | c.916A>T p.R306W | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.013); catalogued as COSV100041571; called by muse, mutect2, varscan2
- PAG1 | c.1101A>C p.K367N | Missense Mutation (SNP) | VAF 89/209 reads (43%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV99597044; called by muse, mutect2, varscan2
- PDE1A | c.176C>T p.A59V | Missense Mutation (SNP) | VAF 34/189 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs1418750796, COSV100113096; called by muse, mutect2, varscan2
- PLXNB2 | c.1100A>G p.E367G | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV100833864; called by muse, mutect2, varscan2
- PPP1R9B | c.785C>T p.S262L | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.017); catalogued as COSV100380632; called by muse, mutect2, varscan2
- PRR16 | c.617G>A p.R206Q (on ENST00000407149 / NM_001300783.2; = p.R183Q on NM_016644.2) | Missense Mutation (SNP) | VAF 29/172 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1162088448, COSV65397343, COSV65404957; called by muse, mutect2, varscan2
- RPS6KA6 | c.1541G>A p.C514Y | Missense Mutation (SNP) | VAF 41/309 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99424139, COSV99425304; called by muse, mutect2, varscan2
- TARBP1 | c.4108A>T p.I1370F | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.087); catalogued as COSV99241123; called by muse, mutect2, varscan2
- TMEM87B | c.134A>C p.E45A | Missense Mutation (SNP) | VAF 23/195 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.026); catalogued as COSV51719188; called by muse, mutect2, varscan2
- TRIM23 | c.301C>T p.R101* | Nonsense Mutation (SNP) | VAF 188/421 reads (45%) | catalogued as rs766787623, COSV51549720; called by muse, mutect2, varscan2
- USP37 | c.1021C>T p.Q341* | Nonsense Mutation (SNP) | VAF 48/119 reads (40%) | catalogued as COSV99294124; called by muse, mutect2, varscan2
- ZNFX1 | c.1130G>T p.R377L | Missense Mutation (SNP) | VAF 68/181 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100870738; called by muse, mutect2, varscan2
- ATG14 | c.58dup p.R20Pfs*67 | Frame Shift Ins (INS) | VAF 41/100 reads (41%) | called by mutect2, pindel, varscan2
- BAP1 | c.1094A>C p.N365T | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); called by muse, varscan2
- BAP1 | c.1075_1084del p.A359Tfs*68 | Frame Shift Del (DEL) | VAF 14/43 reads (33%) | called by pindel, varscan2
- GMPR2 | c.858-6_858-1del p.X286_splice (on ENST00000355299 / NM_001351022.2; = p.X304_splice on NM_016576.5) | Splice Site (DEL) | VAF 47/147 reads (32%) | called by mutect2, pindel, varscan2
- HIPK2 | c.1541_1546del p.K514_R515del | In Frame Del (DEL) | VAF 25/138 reads (18%) | called by mutect2, pindel, varscan2
- KANSL2 | c.-9-6_6del | Splice Site (DEL) | VAF 21/88 reads (24%) | called by mutect2, pindel, varscan2
- TLL1 | c.2069_2073del p.G690Vfs*5 | Frame Shift Del (DEL) | VAF 17/89 reads (19%) | called by mutect2, pindel, varscan2
- TRIM13 | c.259dup p.I87Nfs*23 | Frame Shift Ins (INS) | VAF 18/85 reads (21%) | called by mutect2, pindel, varscan2
- AC136428.1 | c.195G>A p.E65= | Silent (SNP) | VAF 28/232 reads (12%) | catalogued as COSV101434942; called by muse, mutect2, varscan2
- C8A | c.1524C>T p.P508= | Silent (SNP) | VAF 116/467 reads (25%) | catalogued as rs750037540, COSV100776445; called by muse, mutect2, varscan2
- CARMIL2 | c.3183G>A p.E1061= | Silent (SNP) | VAF 14/41 reads (34%) | catalogued as rs746664772, COSV99537438; called by muse, mutect2, varscan2
- GRIK3 | c.234C>A p.T78= | Silent (SNP) | VAF 38/121 reads (31%) | catalogued as COSV100901396, COSV66137921; called by muse, mutect2, varscan2
- HGSNAT | c.1758C>T p.H586= | Silent (SNP) | VAF 16/96 reads (17%) | catalogued as rs1420418918, COSV52819294, COSV99925109; called by muse, mutect2, varscan2
- HOXB6 | c.237C>T p.A79= | Silent (SNP) | VAF 66/112 reads (59%) | catalogued as rs577327660, COSV99494376; called by muse, mutect2, varscan2
- MYH14 | c.27C>T p.P9= | Silent (SNP) | VAF 10/49 reads (20%) | catalogued as rs1034339867, COSV99221852; called by muse, mutect2, varscan2
- PAPOLG | c.1296C>T p.Y432= | Silent (SNP) | VAF 24/249 reads (10%) | catalogued as rs927949343, COSV53182498; called by muse, mutect2, varscan2
- PARPBP | c.873C>T p.G291= | Silent (SNP) | VAF 49/157 reads (31%) | catalogued as rs1186321456, COSV100569003; called by muse, mutect2, varscan2
- PYCR2 | c.312G>A p.V104= | Silent (SNP) | VAF 11/66 reads (17%) | catalogued as rs761614919, COSV100661480; called by muse, mutect2, varscan2
- TACC3 | c.2370G>A p.Q790= | Silent (SNP) | VAF 65/124 reads (52%) | catalogued as COSV100508517; called by muse, mutect2, varscan2
- TGFBRAP1 | c.1602C>G p.T534= | Silent (SNP) | VAF 24/164 reads (15%) | catalogued as COSV99304742, COSV99304770; called by muse, mutect2, varscan2
- TMEM168 | c.1605C>A p.S535= | Silent (SNP) | VAF 16/60 reads (27%) | catalogued as COSV100454506, COSV100454592; called by muse, mutect2, varscan2
